Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A15W, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A15W-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium

C54.1

Surgical Pathology

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 C1 C2 C3
C4 C5 D1 D2
D3 D4 D5 D6 E1 E2 E3 E4 E5
Uterus, right ovary (2.0 x 1.5 x 0.9 cm) with 5.9 cm
segment of
right fallopian tube, and left ovary (1.9 x 1.8 x 0.9 cm)
with 7.3
cm segment of left fallopian tube together weighing 95.0
grams,
separately submitted tissue from the pelvic peritoneum
(biopsy, 1.4
x 1.0 x 0.2 cm), right and left pelvic lymph nodes and
left
para-aortic nodes.

DIAGNOSIS:

Uterus, bilateral ovaries, and fallopian tubes; total
abdominal
hysterectomy and bilateral salpingo-oophorectomy:
Invasive FIGO
grade I (of III) endometrial adenocarcinoma, endometrioid
type
forming a mass (8.5 x 2.6 x 1.1 cm) invading 0.7 cm into
the 1.8 cm
myometrial thickness. Tumor locally involves the lower
uterine
segment. The cervix is uninvolved.

Ovary, right, oophorectomy: Focus of endometriosis.

Ovary, left, oophorectomy: Without diagnostic
abnormality.

Fallopian tubes, right and left, salpingectomies: Without
diagnostic abnormality.

Soft tissue, pelvic peritoneum, biopsy: Inflamed
fibroconnective
tissue.

Lymph nodes, right pelvic, lymphadenectomy: Multiple (11
external

[page 2 of 2]
iliac, 4 common iliac, 1 internal iliac and 3 obturator)
are
negative for tumor.

Lymph nodes, left pelvic, lymphadenectomy: A single left
pelvic
obturator (of 9) is positive for metastatic
adenocarcinoma. Multiple
(1 external iliac, 4 common iliac, 1 internal iliac) are
negative
for tumor.

Lymph nodes, left para-aortic, lymphadenectomy: Multiple
(8) left
para-aortic lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file f6ae01f7-2fe0-42af-b123-19900096a532 (TCGA-D1-A15W.1C938760-9492-4F4E-87CE-85CE3C15BBCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).